Gene-level copy-number profile of tumor specimen TCGA-BC-A10T-01A from TCGA case TCGA-BC-A10T, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G1; Age at diagnosis: 76.5 years (27,944 days).
Specimen TCGA-BC-A10T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.9a56f797-4a27-48f5-8a42-115baed0c396.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BC-A10T-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1f25b366-8e86-4c94-9965-654e06012f35

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 9,569; copy number 2: 42,009; copy number 3: 7,949; copy number 4: 164; copy number 5: 104; copy number 6: 5; copy number 7: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BC-A10T-01A-11D-A12Y-01): tumor purity 0.7, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 127 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:154,937,370–155,244,699, 35 genes, copy number 5: AL451085.1, PBXIP1, Metazoa_SRP, PYGO2, AL451085.2, SHC1, CKS1B, MIR4258, FLAD1, LENEP, ZBTB7B, DCST2, DCST1, DCST1-AS1, ADAM15, EFNA4, AL691442.1, EFNA3, Y_RNA, EFNA1, SLC50A1, DPM3, HMGN2P18, KRTCAP2, AL713999.2, TRIM46, MUC1, THBS3-AS1, MIR92B, THBS3, MTX1, AC234582.1, GBAP1, MTX1P1, GBA.
- chr1:234,373,456–234,683,176, 13 genes, copy number 5 (within-gene range 3–5): COA6, TARBP1, LINC01354, AL161640.2, AL161640.3, AL161640.1, U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4.
- chr3:172,425,850–172,725,038, 10 genes, copy number 7: BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2.
- chr5:113,022,099–113,488,823, 3 genes, copy number 5 (within-gene range 3–5): MCC, AC079465.1, TSSK1B.
- chr5:115,738,978–115,841,837, 5 genes, copy number 6: AC008549.1, H3P24, RNU2-49P, CDO1, ATG12.
- chr8:100,337,595–100,559,784, 8 genes, copy number 7: AP001574.1, AP003472.1, MIR4471, AP003472.2, AP000424.1, AP000424.2, ANKRD46, GAPDHP62.
- chr8:117,520,713–117,540,262, 2 genes, copy number 5: MED30, RPS10P16.
- chr8:125,091,679–125,541,373, 5 genes, copy number 5: NSMCE2, RN7SL329P, AC084083.1, TRIB1, AC091114.1.
- chr8:133,036,728–133,571,940, 11 genes, copy number 5 (within-gene range 3–5): SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3.
- chr11:114,159,791–114,161,166, 1 gene, copy number 5: AP002755.1.
- chr12:12,116,025–12,267,044, 1 gene, copy number 5 (within-gene range 2–5): LRP6.
- chr12:12,226,674–12,562,863, 10 genes, copy number 5 (within-gene range 3–5): RNU6-545P, AC007621.3, RNU6-318P, MANSC1, RPL23AP66, LOH12CR2, BORCS5, AC007619.2, DUSP16, AC007619.1.
- chr17:1,464,186–2,025,334, 23 genes, copy number 5: MYO1C, INPP5K, PITPNA-AS1, PITPNA, SLC43A2, RN7SL105P, SCARF1, RILP, PRPF8, AC130343.3, TLCD2, MIR22HG, MIR22, WDR81, AC130343.1, SERPINF2, SERPINF1, SMYD4, RPA1, AC130689.1, RTN4RL1, AC099684.2, AC099684.1.

Autosomal genes at a single copy (total copy number 1): 7,196. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
